CTSP case CTSP-AD2E — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4ad1f10e-b45d-4bed-bc99-f3d48254623d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 62.6 years (22,857 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage II; Days to last follow up: 1,800 days (4.9 years); Best overall response: Partial Response; Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): Low Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 91 kg; Height: 152 cm; BMI: 39.4.

Biospecimens (1 sample)
- Sample DLBCL11331-sample: Sample type: Tumor; Tissue type: Tumor.
